Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A85E, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A85E-01A (Primary Tumor).

[page 1 of 2]
Patient:

Path#

Accessioned

Birthdate:

(Age

Loc:

Gender: F

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1-2. BRAIN TUMOR (RESECTION): LOW GRADE OLIGOASTROCYTOMA (WHO GRADE II). SEE NOTE.

NOTE: Histologic sections demonstrate a cellular glioma with astrocytic and focal oligodendroglial features. There is low level mitotic activity (approximately 2 mitoses/10 high power fields in areas). p53 is strongly positive in numerous tumor cells. The MIB-1 labeling index shows patchy increases. Molecular microsatellite studies show 19q loss with intact 1p.

[REDACTED]

*Electronic signature

=====

GROSS DESCRIPTION

(Continued on next page.)

ICD.O. 3
Oligoastrocytoma, grade II 9382/2
CLCE
Site: Brain, supratentorial NOS
path
Brain NOS C71.0
JTD 6/10/14

[page 2 of 2]
Patient: [REDACTED]

Path# [REDACTED]

MR # [REDACTED]

Page 2

**SURGICAL
PATHOLOGY**

=====

PART #1: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]
Other Pathologists / [REDACTED]

FS.: BRAIN TUMOR: INFILTRATIVE GLIOMA. DEFER FOR GRADING.

Dictated by: [REDACTED]

The specimen is received in saline for frozen section labeled with the patient's name, [REDACTED] and designated 'brain tumor'. It consists of three (3) tan-white, pink fragments of soft tissue measuring 1.2 x 0.6 x 0.4 cm in aggregate. The specimen is wrapped in lens paper and entirely submitted.

SUMMARY OF SECTIONS:

1 - FSC - 1
1 - A - 2
2 - TOTAL - 3

PART #2: BRAIN TUMOR

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'brain tumor'. It consists of multiple portions of pink to gray white soft tissue, aggregating to 3.5 x 2.7 x 1.6 cm. The specimen is wrapped in tissue paper and entirely submitted.

SUMMARY OF SECTIONS:

1 - A ----
1 -TOTAL -----

Other Surgical Pathology Specimens known to the computer: [REDACTED]

=====

(End of Report)

printed

Pathology Discrepancy		✓
For Malignancy History		✓
Not Synchronous Primary Tumor		✓

Source: NCI Genomic Data Commons file 6e441e21-629d-476d-8137-0a5627831c62 (TCGA-WY-A85E.BD5E04AC-1E0D-400E-B5A8-A08844543CE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).